Somatic mutation profile of tumor specimen 0DOO1J from CCDI case PBBYLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,372 days).
Specimen 0DOO1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6a4844-57b8-4574-bc5b-c50d3994c09a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOOCS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79fa0ab8-0a1f-4030-bb12-b921299eee90

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Splice Region 1, Silent 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 291/1006 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MROH2A | c.4902T>C p.N1634= | Splice Region (SNP) | VAF 240/982 reads (24%) | catalogued as rs1467066199; called by muse, mutect2, varscan2
- BNIP5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- TTN | c.38277T>G p.N12759K (on ENST00000591111; = p.N5335K on NM_003319.4) | Missense Mutation (SNP) | VAF 116/673 reads (17%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF280A | c.1519T>C p.S507P | Missense Mutation (SNP) | VAF 35/1071 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2
- RIPK1 | c.681A>G p.P227= | Silent (SNP) | VAF 40/564 reads (7%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/285 reads (3%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- PEAR1 | c.903-28C>T | Intron (SNP) | VAF 13/232 reads (6%) | catalogued as rs1180636178, COSV52775469; called by muse, mutect2
